Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9JO, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9JO-01A (Primary Tumor).

[page 1 of 2]
*Carcinoma, papillary renal
cell 8260/3
Site @ Kidney NOS C64.9
JW 4/28/14*

Pathology Report

Final Diagnosis

- A. RIGHT KIDNEY, PARTIAL NEPHRECTOMY:
Renal cell carcinoma with hybrid oncocytic features and focal papillary features. See Key Pathologic Findings.
Surgical margin, free of malignancy.
Pathologic stage: pT1b NX MX.
- B. DEEP MARGIN:
Renal parenchyma, free of malignancy.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by _____

Ancillary Testing

Immunohistochemical stains (AMACR, cytokeratin 7, cytokeratin 20, CD117, vimentin) performed with appropriate positive and negative controls on blocks A3 and A5 support the diagnosis. Immunohistochemical stain (RCC antigen) performed with appropriate positive and negative control on block A5 supports the diagnosis. Special stain (Hale's colloidal iron) performed with appropriate control on block A5 supports the diagnosis.

Key Pathological Findings

A: Kidney Resection
PROCEDURE:
Partial nephrectomy
SPECIMEN LATERALITY:
Right
TUMOR SIZE (largest tumor if multiple):
Dimension: 4.5 cm
MACROSCOPIC EXTENT OF TUMOR:
Tumor limited to kidney
HISTOLOGIC TYPE:
Renal cell carcinoma with hybrid oncocytic features and focal papillary features
SARCOMATOID FEATURES:
Not identified
HISTOLOGIC GRADE (Fuhrman Nuclear Grade):
G3: Nuclei very irregular, approximately 20 microns; nucleoli large and prominent
MICROSCOPIC TUMOR EXTENSION:
Tumor limited to kidney
MARGINS:
Margins uninvolved by carcinoma
ADRENAL GLAND:
Not present
PERINEURAL INVASION:
Absent

[page 2 of 2]
ANGIOLYMPHATIC INVASION:

Absent

LYMPH-VASCULAR INVASION:

Absent

PRIMARY TUMOR (pT):

pT1b: Tumor more than 4 cm but not more than 7 cm in greatest dimension, limited to the kidney

REGIONAL LYMPH NODES (pN):

pNX: Regional lymph nodes cannot be assessed

DISTANT METASTASIS (pM):

pMX

Specimen(s) Received

- A RIGHT PARTIAL NEPHRECTOMY FS
B DEEP MARGIN FS

Preoperative Diagnosis

Right renal mass

Intraoperative Consultation

FSA1: RIGHT PARTIAL NEPHRECTOMY, INK EQUALS MARGIN:
Oncocytic lesion, margin negative.

FSB1: DEEP MARGIN, INK IS MARGIN:
Negative.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr.

I, _____, have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. Specimen A is received fresh for frozen section analysis labeled "right partial nephrectomy ink equals margin." The specimen consists of a 5.5 x 5.5 x 4.0 cm partial nephrectomy. The surgical margin resection is marked with black ink. Serial sectioning reveals a soft, red-brown mass (4.5 x 4.5 x 3.0 cm) grossly abutting the surgical margin resection. The overlying capsule is intact and marked with blue ink. The remainder of the renal parenchyma is red-brown and grossly unremarkable. Representative frozen sections taken and submitted as FSA1. Representative section of the tumor submitted to the Tissue Procurement Laboratory.

Permanent representative sections are submitted as:

- A2: Mirror image of tumor submitted to the Tissue Bank.
A3: Tumor shown in its relationship to overlying capsule.
A4-A7: Representative sections of tumor showing its relationship to adjacent tissue.
A8: Grossly unremarkable renal parenchyma.

B. Specimen B is received fresh for frozen section analysis labeled "deep margin, ink is margin." The specimen consists of 1.5 x 0.2 x 0.1 cm soft, tan-pink, irregular fragment of renal parenchyma, which is marked with ink on the surgical margin resection." The specimen is serially resectioned and entirely submitted for frozen section as FSB1.

Source: NCI Genomic Data Commons file 2cbcca10-329d-40cc-a323-7615cea04215 (TCGA-2Z-A9JO.69FF5548-F1B0-452F-B77B-405479A5993D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).